Somatic mutation profile of tumor specimen MP2PRT-PAUABA-TMP1-A (aliquot MP2PRT-PAUABA-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUABA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,738 days).
Specimen MP2PRT-PAUABA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe5646b9-1db9-43d0-a6e7-1026f2ac5222.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUABA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUABA-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/991da3f7-13a1-4c54-b871-38ec807e2968

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 3'Flank 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD4 | c.3979C>T p.R1327C (on ENST00000357008 / NM_001363606.2; = p.R1340C on NM_001273.5) | Missense Mutation (SNP) | VAF 38/790 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58896099, COSV58902501; called by muse, mutect2
- CHD4 | c.2830C>T p.R944W (on ENST00000357008 / NM_001363606.2; = p.R957W on NM_001273.5) | Missense Mutation (SNP) | VAF 162/642 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58896897; called by muse, mutect2, varscan2
- PCDHAC1 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 28/630 reads (4%) | catalogued as rs782446148, COSV53836650; called by muse, mutect2
- TMEM132C | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 142/443 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs371618019; called by muse, mutect2, varscan2
- CCDC90B | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAH3 | c.10739A>T p.N3580I | Missense Mutation (SNP) | VAF 206/577 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DNAH9 | c.8992C>A p.Q2998K | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.098); called by muse, mutect2
- FCRL5 | c.2186C>G p.A729G | Missense Mutation (SNP) | VAF 39/757 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZFR2 | c.2470G>A p.A824T | Missense Mutation (SNP) | VAF 226/698 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ZNF462 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 36/698 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.351); called by muse, mutect2
- KCNQ2 | c.1776C>T p.I592= (on ENST00000359125 / NM_172107.4; = p.I564= on NM_004518.6) | Silent (SNP) | VAF 125/388 reads (32%) | catalogued as rs201868078, CM083708, COSV60540779, COSV60553426; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP10 | c.1050G>A p.A350= | Silent (SNP) | VAF 229/624 reads (37%) | called by muse, mutect2, varscan2
- TEX15 | c.5028T>C p.N1676= (on ENST00000256246; = p.N2059= on NM_001350162.2) | Silent (SNP) | VAF 60/199 reads (30%) | called by muse, mutect2, varscan2
- WDR87 | c.5934T>C p.V1978= | Silent (SNP) | VAF 110/288 reads (38%) | catalogued as rs1244499058; called by muse, mutect2, varscan2
- IGHV2-70 | chr14:106770576 ins GCCC | 3'Flank (INS) | VAF 57/185 reads (31%) | called by mutect2, pindel, varscan2
- PDZD7 | chr10:101015712 C>T | 3'Flank (SNP) | VAF 276/724 reads (38%) | catalogued as rs901875344; called by muse, mutect2, varscan2
